Surgical pathology report (de-identified scan), TCGA case TCGA-41-3392, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Christiana Healthcare, specimen TCGA-41-3392-01A (Primary Tumor).

[page 1 of 2]
SPECIMEN

- A. Frontal brain tumor
- B. Frontal brain tumor
- C. Tissue procurement specimen
- D. Deep frontal mass

CLINICAL NOTES

--

FROZEN SECTION DIAGNOSIS

FSA) Frontal lobe - Diffuse glioma; final classification deferred to permanent sections.

FSB) Frontal brain mass - Malignant astrocytoma, at least grade 3 on frozen section. Final diagnosis deferred to permanent sections.

GROSS DESCRIPTION

- A. Received fresh for frozen section labeled "right frontal bone tumor" are irregularly-shaped fragments of tan tissue that measure 1.3 x 1.1 x up to 0.3 cm in dimension. The tissue is entirely frozen.
- B. Submitted fresh for frozen labeled "frontal brain tumor" are multiple portions of brain tissue. The largest is an intact portion of what appears to be cortex measuring 2 x 2 x 1.5 cm. Sectioning this shows it to be mostly brown in color with some areas of creamy white discoloration. Multiple fragments of reddish brown soft tissue are also present. All of the small soft tissue fragments and a small portion of the larger fragment is submitted for frozen section. AS-2.
- D. Received fresh labeled "deep frontal mass" is a 0.8 x 0.3 x 0.1 cm. portion of soft, dusky tan pink-gray tissue which is submitted in toto. AS-1

[page 2 of 2]
[REDACTED]

MICROSCOPIC DESCRIPTION

This case is sent to [REDACTED] at [REDACTED] for
consultative review. [REDACTED] states the following
in [REDACTED] consultation letter.

"I have examined your micro sections of this [REDACTED]
male wherein I find a WHO grade IV (of IV) small cell and
fibrillary astrocytoma (glioblastoma multiforme).

14x2, 3x3

DIAGNOSIS

A, B and D. Brain, frontal tumor, biopsy -- WHO grade IV (of IV)
small cell and fibrillary astrocytoma.

Palisading necrosis is noted [REDACTED]

C. Brain, frontal tumor, excision -- Tissue taken for tissue
procurement.

[REDACTED]

--- End Of Report ---

Source: NCI Genomic Data Commons file ea5ea783-b3e6-4f22-a7d5-536e72cb2a70 (TCGA-41-3392.FF6E82B9-5802-4EDC-8310-32615B9511EB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).